Somatic mutation profile of tumor specimen C3L-02643-01 (aliquot CPT0204430007) from CPTAC case C3L-02643, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 67.9 years (24,797 days).
Specimen C3L-02643-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 530b1f04-9758-4059-b82b-3b0b9f3e0389.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02643-31 (Blood Derived Normal), aliquot CPT0204570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29a305c8-ad27-4a3d-a401-71dbafc0dd7a

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 61/155 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IQCH | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs375810750, COSV100245532; called by muse, mutect2, varscan2
- MAP3K11 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as rs747732702; called by muse, mutect2, varscan2
- MFF | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.336); catalogued as rs995212395; called by muse, mutect2
- NEUROD4 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs777820884; called by muse, mutect2, varscan2
- PCDHA1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 58/484 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as rs781798156, COSV65375867; called by muse, mutect2, varscan2
- SAMD9 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1404457838; called by muse, mutect2, varscan2
- TMEM235 | c.273G>A p.L91= | Splice Region (SNP) | VAF 26/150 reads (17%) | catalogued as rs1447715421, COSV66577144; called by muse, mutect2, varscan2
- TMEM87A | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs1349632476; called by muse, mutect2, varscan2
- TMF1 | c.3242A>G p.K1081R | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as rs1299008449; called by muse, mutect2, varscan2
- COL4A3 | c.4331G>T p.R1444I | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- CRB1 | c.209T>A p.M70K | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- FSCB | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FZR1 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGHE | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF22 | c.1936dup p.E646Gfs*? | Frame Shift Ins (INS) | VAF 30/286 reads (10%) | called by mutect2, pindel, varscan2
- MALRD1 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- MAP1LC3A | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- NAGK | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE2A | c.2046-2A>G p.X682_splice | Splice Site (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- PRKCQ | c.995G>T p.C332F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETDB1 | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- SPTLC3 | c.825_826+2dup | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- SYNE2 | c.19063G>A p.E6355K | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZNF711 | c.2112C>A p.Y704* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- ADD2 | c.1254C>G p.A418= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- CEP152 | c.3750C>T p.A1250= (on ENST00000380950 / NM_001194998.2; = p.A1194= on NM_014985.4) | Silent (SNP) | VAF 18/504 reads (4%) | called by muse, mutect2
- NAALADL2 | c.2385T>C p.N795= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs760584843, COSV71986889; called by muse, mutect2, varscan2
- PDK2 | c.858C>T p.I286= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- SORCS3 | c.3483C>T p.H1161= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs768149623; called by muse, mutect2, varscan2
- C16orf97 | n.337C>T | RNA (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
